Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8558, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8558-01A (Primary Tumor).

Pathology Report for Subject:

Addendum Discussion:

MIB-1 reactive cells tend to be grouped in several regions of the slide. The majority of the tumor demonstrates a labeling index of <0.1%. In the most proliferative areas, the labeling index is 2.9%.

Addendum Diagnosis:

Left Posterior Temporal Tumor

- Oligodendroglioma, grade II
- MIB-1 labeling index = 2.9%

Microscopic Description:

Sections demonstrate a mildly hypercellular glial neoplasm, the cells of which resemble mildly atypical oligodendrocytes. No mitotic figures are seen. There is no microvascular or necrosis. The tumor diffusely infiltrates the gray and white matter.

Source: NCI Genomic Data Commons file c0ba3722-f4d6-4418-b0ba-95f13f282650 (TCGA-HT-8558.3F364926-441B-435D-BDF5-E055B46A1B1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).